Gene-level copy-number profile of tumor specimen TCGA-QR-A70Q-01A from TCGA case TCGA-QR-A70Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 33.9 years (12,394 days).
Specimen TCGA-QR-A70Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 59c0501e-868f-41a2-95a8-3e741ab8ac69.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-QR-A70Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/54d64a76-05bf-4a7a-b80c-c3549250dc5f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 6,363; copy number 3: 2,545; copy number 4: 48,646; copy number 5: 849; copy number 6: 481; copy number 7: 20.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
